Gene-level copy-number profile of tumor specimen TCGA-19-1392-01A from TCGA case TCGA-19-1392, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.8 years (26,593 days).
Specimen TCGA-19-1392-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.443dfcb5-e0bf-4885-a872-562648441ea0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-19-1392-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0cfb374b-cd3d-40a4-a013-5f32578e6e23

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 256; copy number 2: 8,110; copy number 3: 10,648; copy number 4: 34,251; copy number 5: 2,863; copy number 6: 3,371; copy number 7: 172; copy number 9: 7; copy number 10: 21; copy number 12: 29; copy number 14: 88.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-19-1392-01): tumor purity 1, ploidy 3.76, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 145 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:46,884,362–47,701,523, 21 genes, copy number 10 (within-gene range 1–10): GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2, ITFG1-AS1, RPL23AP72, ITFG1, AC007494.2, AC007494.3, AC007494.1, AC007533.1, Y_RNA, 5S_rRNA, PHKB, RNA5SP425, AC007599.2, AC007599.1, EIF4BP5, NDUFA5P11.
- chr16:71,366,933–71,489,311, 7 genes, copy number 9 (within-gene range 2–9): LINC02136, AC010547.6, TLE7, AC010547.5, ZNF23, AC010547.4, AC010547.1.
- chr19:15,141,105–15,729,060, 29 genes, copy number 12: OR10B1P, RNU6-782P, NOTCH3, MIR6795, AC004257.1, EPHX3, BRD4, AC005776.1, AC005776.2, AKAP8, AC005785.1, AKAP8L, AC005785.2, AC006128.1, WIZ, MIR1470, RASAL3, PGLYRP2, CYP4F22, AC011492.1, CYP4F23P, AD000091.1, RPL23AP2, AC093072.1, CYP4F8, CYP4F3, CYP4F10P, CYP4F12, OR10H2.
- chr19:49,429,401–50,659,310, 88 genes, copy number 14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 250. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
